Somatic mutation profile of tumor specimen MP2PRT-PAVWVN-TMP1-A (aliquot MP2PRT-PAVWVN-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVWVN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,656 days).
Specimen MP2PRT-PAVWVN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ca61da5-7873-4a4b-a189-6b01d8967fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVWVN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVWVN-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4632e12e-1600-4a4e-9ecb-629fe01f04d9

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/299 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 37/338 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MKRN3 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs373400101; called by muse, mutect2, varscan2
- TSC2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs764529584, COSV54763779; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- AMZ1 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 61/546 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.058); called by muse, mutect2
- ERF | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 263/612 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM133A | c.226del p.S76Afs*6 | Frame Shift Del (DEL) | VAF 35/56 reads (63%) | called by mutect2, pindel, varscan2
- KCTD8 | c.1043G>A p.S348N | Missense Mutation (SNP) | VAF 113/323 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- OR9Q1 | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A2 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 155/416 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYCP2L | c.789C>A p.F263L | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NAB1 | c.351T>C p.S117= | Silent (SNP) | VAF 140/340 reads (41%) | called by muse, mutect2, varscan2
- TTC34 | c.264G>A p.S88= | Silent (SNP) | VAF 298/681 reads (44%) | catalogued as rs1457783617; called by muse, mutect2, varscan2
- DLG2 | c.205-65554G>A | Intron (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
